Somatic mutation profile of tumor specimen TCGA-HZ-A9TJ-01A (aliquot TCGA-HZ-A9TJ-01A-11D-A40W-08) from TCGA case TCGA-HZ-A9TJ, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 70.8 years (25,849 days).
Specimen TCGA-HZ-A9TJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a2b4b772-728e-4314-be08-7c624cc22a8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A9TJ-10A (Blood Derived Normal), aliquot TCGA-HZ-A9TJ-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/951394de-a428-4fa6-81eb-b4dbdb30de69

The open-access MAF lists 91 somatic variants for this specimen: 66 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 22, Nonsense Mutation 7, Frame Shift Del 2, Splice Site 2, RNA 2, In Frame Del 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 325/532 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58690205, COSV58691614; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 72/283 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 152/388 reads (39%) | catalogued as rs193922464, CM114804; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 88/182 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCG8 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 121/385 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs202028007, COSV99699353; called by muse, mutect2, varscan2
- ALCAM | c.1717A>G p.K573E | Missense Mutation (SNP) | VAF 36/318 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60254873; called by muse, mutect2, varscan2
- ASTN2 | c.857A>T p.E286V | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100523635, COSV100525062; called by muse, mutect2
- BFSP2 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 51/346 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV100183843, COSV56591758; called by muse, mutect2, varscan2
- CADM2 | c.572G>A p.R191Q (on ENST00000407528 / NM_001167674.2; = p.R193Q on NM_153184.4) | Missense Mutation (SNP) | VAF 80/235 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs150681488; called by muse, mutect2, varscan2
- CD8B | c.238A>C p.I80L | Missense Mutation (SNP) | VAF 51/466 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100514331; called by muse, mutect2, varscan2
- CELSR1 | c.1307C>G p.P436R | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53090885, COSV99416363; called by muse, mutect2, varscan2
- COL11A1 | c.3443C>G p.P1148R | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100614473; called by muse, mutect2, varscan2
- CUBN | c.10205C>T p.A3402V | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.438); catalogued as rs758386041, COSV100911875; called by muse, mutect2, varscan2
- DLGAP2 | c.2819C>T p.P940L | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373082856; called by muse, mutect2, varscan2
- DRC7 | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568917398, COSV61054416; called by muse, mutect2, varscan2
- DSP | c.1829C>G p.S610C | Missense Mutation (SNP) | VAF 48/814 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV101131156; called by muse, mutect2
- FAM135B | c.1630G>T p.E544* | Nonsense Mutation (SNP) | VAF 22/275 reads (8%) | catalogued as COSV99417328; called by muse, mutect2
- FARP2 | c.29T>A p.V10D | Missense Mutation (SNP) | VAF 115/316 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV99883604; called by muse, mutect2, varscan2
- FARP2 | c.998T>A p.V333D | Missense Mutation (SNP) | VAF 57/381 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99883606; called by muse, mutect2, varscan2
- FMNL3 | c.1966C>T p.R656C | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.736); catalogued as rs770930654, COSV53301070; called by muse, mutect2, varscan2
- GPR21 | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 35/682 reads (5%) | catalogued as rs370055199; called by muse, mutect2
- HCN1 | c.2455G>A p.V819M | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs1197215604, COSV57493912; called by muse, mutect2
- IRS1 | c.2569del p.R857Gfs*86 | Frame Shift Del (DEL) | VAF 39/373 reads (10%) | catalogued as COSV100524798; called by mutect2, pindel, varscan2
- KCNA1 | c.1355C>A p.S452Y | Missense Mutation (SNP) | VAF 168/1263 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.91); catalogued as COSV101230084; called by muse, mutect2, varscan2
- KCNIP2 | c.520C>T p.R174W (on ENST00000356640 / NM_173191.3; = p.R189W on NM_014591.5) | Missense Mutation (SNP) | VAF 21/363 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1398216871, COSV53306090; called by muse, mutect2
- KRTAP5-3 | c.202G>A p.G68S | Missense Mutation (SNP) | VAF 36/538 reads (7%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.517); catalogued as COSV101294483; called by muse, mutect2
- L1CAM | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 67/229 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.076); catalogued as COSV100648817; called by muse, mutect2, varscan2
- LRBA | c.5246T>C p.V1749A | Missense Mutation (SNP) | VAF 91/371 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.251); catalogued as COSV100840767; called by muse, mutect2, varscan2
- LRRC7 | c.328C>T p.R110* (on ENST00000651989 / NM_001370785.2; = p.R77* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 143/517 reads (28%) | catalogued as COSV50415481, COSV50652183; called by muse, mutect2, varscan2
- LRRC7 | c.4444C>A p.P1482T (on ENST00000651989 / NM_001370785.2; = p.P1402T on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/240 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.632); catalogued as COSV99223796; called by muse, mutect2, varscan2
- MCF2L2 | c.1256A>T p.K419I | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV100190878; called by muse, mutect2
- MTG2 | c.410G>A p.G137E | Missense Mutation (SNP) | VAF 33/677 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895119; called by muse, mutect2
- MUC17 | c.4523C>T p.T1508M | Missense Mutation (SNP) | VAF 112/1364 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as rs374713003; called by muse, mutect2
- MYO5A | c.2099+1G>A p.X700_splice | Splice Site (SNP) | VAF 84/557 reads (15%) | catalogued as COSV100697188; called by muse, mutect2, varscan2
- NECAB1 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 19/260 reads (7%) | catalogued as COSV101340983, COSV70240145; called by muse, mutect2
- NTNG2 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.318); catalogued as rs557724992, COSV100647178, COSV100647253; called by muse, mutect2
- NUP205 | c.4171A>G p.I1391V | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99606295; called by muse, mutect2
- OSBPL5 | c.701G>A p.W234* | Nonsense Mutation (SNP) | VAF 50/120 reads (42%) | catalogued as COSV99719866, COSV99720698; called by muse, mutect2, varscan2
- OTOF | c.4354C>T p.R1452C (on ENST00000272371 / NM_194248.3; = p.R685C on NM_004802.4) | Missense Mutation (SNP) | VAF 35/226 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs560665036, COSV55510335; called by muse, mutect2, varscan2
- PCDHGB4 | c.2026C>T p.R676C | Missense Mutation (SNP) | VAF 94/526 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.489); catalogued as rs1417147488, COSV53967357; called by mutect2, varscan2
- PDE3A | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 32/332 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV100761509; called by muse, mutect2
- PFKFB4 | c.1031A>T p.Y344F | Missense Mutation (SNP) | VAF 17/191 reads (9%) | PolyPhen benign (0.013); catalogued as COSV99219247; called by muse, mutect2
- PKP2 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 39/892 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs775789180, COSV99297048; called by muse, mutect2
- PLEKHH2 | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 118/539 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1310606168, COSV99174258; called by muse, mutect2, varscan2
- PRR5L | c.641T>A p.V214E | Missense Mutation (SNP) | VAF 74/389 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100286750; called by muse, mutect2, varscan2
- RBM27 | c.2942G>A p.G981E | Missense Mutation (SNP) | VAF 35/306 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99505545; called by muse, mutect2, varscan2
- RP1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 13/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs934067828, COSV55127174; called by muse, mutect2
- SLC12A2 | c.2201C>G p.A734G | Missense Mutation (SNP) | VAF 58/397 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV52469967, COSV99320408; called by muse, mutect2, varscan2
- SLC12A5 | c.3192C>T p.N1064= (on ENST00000454036 / NM_001134771.2; = p.N1041= on NM_020708.5) | Splice Region (SNP) | VAF 56/451 reads (12%) | catalogued as COSV99275080; called by muse, mutect2, varscan2
- SLC2A10 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 93/759 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs759243623, COSV63716002; called by muse, mutect2, varscan2
- SLC9A9 | c.1477G>A p.V493M | Missense Mutation (SNP) | VAF 115/697 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs775249012, COSV57216495; called by muse, mutect2, varscan2
- TEX19 | c.439T>C p.W147R | Missense Mutation (SNP) | VAF 85/431 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100330968; called by muse, mutect2, varscan2
- THSD7B | c.3809G>A p.R1270Q (on ENST00000272643; = p.R1268Q on NM_001316349.2) | Missense Mutation (SNP) | VAF 178/575 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as rs750716218, COSV55711536; called by muse, mutect2, varscan2
- TIAM1 | c.4400C>T p.P1467L | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.413); catalogued as rs201116117, COSV54542314; called by muse, mutect2, varscan2
- TIAM1 | c.2090G>T p.W697L | Missense Mutation (SNP) | VAF 60/455 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.11); catalogued as COSV99731932; called by muse, mutect2, varscan2
- TIAM2 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.165); catalogued as rs1299798095, COSV100017738, COSV59706176; called by muse, mutect2
- TMEM117 | c.1362G>T p.Q454H | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV99861489; called by muse, mutect2
- TNNI3K | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 28/572 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs747300364, COSV58547042; called by muse, mutect2
- TTN | c.98876G>A p.W32959* (on ENST00000591111; = p.W25535* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 83/252 reads (33%) | catalogued as COSV100589455; called by muse, mutect2, varscan2
- UBA7 | c.2921T>A p.L974Q | Missense Mutation (SNP) | VAF 104/235 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100323455; called by muse, mutect2, varscan2
- VPS13D | c.6281C>T p.T2094M | Missense Mutation (SNP) | VAF 27/195 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs867243077, COSV50625950; called by muse, mutect2, varscan2
- ZNF638 | c.2732A>G p.N911S | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.079); catalogued as COSV100037751; called by muse, mutect2
- KIF1A | c.2108_2119del p.E703_L706del | In Frame Del (DEL) | VAF 28/189 reads (15%) | called by mutect2, pindel
- NLRP12 | c.683A>G p.H228R | Missense Mutation (SNP) | VAF 20/516 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.07); called by muse, mutect2
- TFAP2C | c.1139_1140del p.P380Rfs*57 | Frame Shift Del (DEL) | VAF 108/492 reads (22%) | called by mutect2, pindel, varscan2
- WTAP | c.145+2dup p.X49_splice | Splice Site (INS) | VAF 38/270 reads (14%) | called by mutect2, pindel, varscan2
- ADGRD1 | c.1983G>A p.V661= | Silent (SNP) | VAF 290/477 reads (61%) | catalogued as COSV99893568; called by muse, mutect2, varscan2
- CDKN2A | c.123G>T p.P41= | Silent (SNP) | VAF 300/512 reads (59%) | catalogued as COSV100444862; called by muse, mutect2
- CNGB1 | c.2454C>T p.L818= | Silent (SNP) | VAF 90/271 reads (33%) | catalogued as rs528283367, COSV51900429; called by muse, mutect2, varscan2
- COL4A2 | c.1209G>A p.P403= | Silent (SNP) | VAF 110/363 reads (30%) | catalogued as rs775959840, COSV64625609, COSV64628387; called by muse, mutect2, varscan2
- DNAH11 | c.699G>A p.P233= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as rs373971291; ClinVar: likely benign; called by muse, mutect2
- EML1 | c.2211G>A p.S737= | Silent (SNP) | VAF 44/299 reads (15%) | catalogued as rs553895497, COSV51748824; called by muse, mutect2, varscan2
- FZD1 | c.405C>T p.P135= | Silent (SNP) | VAF 25/613 reads (4%) | catalogued as COSV99842314; called by muse, mutect2
- GLI2 | c.1773G>A p.P591= (on ENST00000361492 / NM_001374353.1; = p.P608= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/347 reads (12%) | catalogued as rs776509889, COSV100082070; called by muse, mutect2, varscan2
- GPR3 | c.624C>T p.I208= | Silent (SNP) | VAF 16/516 reads (3%) | called by muse, mutect2
- GRIA1 | c.330G>A p.T110= | Silent (SNP) | VAF 121/508 reads (24%) | catalogued as rs370782311, COSV53588479; called by muse, mutect2, varscan2
- HDHD2 | c.159G>A p.K53= | Silent (SNP) | VAF 71/304 reads (23%) | catalogued as COSV100321214; called by muse, mutect2, varscan2
- KIAA1210 | c.18G>T p.T6= | Silent (SNP) | VAF 150/224 reads (67%) | catalogued as COSV68180330, COSV68180653; called by muse, mutect2, varscan2
- MRPL57 | c.78C>T p.F26= | Silent (SNP) | VAF 48/360 reads (13%) | catalogued as COSV100006050; called by muse, mutect2, varscan2
- NCKAP5 | c.3603C>T p.I1201= | Silent (SNP) | VAF 44/283 reads (16%) | catalogued as COSV100489435; called by muse, mutect2, varscan2
- NELL1 | c.1749C>T p.D583= | Silent (SNP) | VAF 68/359 reads (19%) | catalogued as rs758011669, COSV100117908; called by muse, mutect2, varscan2
- OR2M4 | c.825G>A p.S275= | Silent (SNP) | VAF 59/386 reads (15%) | catalogued as rs1399023386, COSV100140911; called by muse, mutect2, varscan2
- PCDH11X | c.1410C>T p.F470= | Silent (SNP) | VAF 170/267 reads (64%) | catalogued as rs768670963, COSV100007108; called by muse, mutect2, varscan2
- PRRC2C | c.3132C>T p.V1044= (on ENST00000367742; = p.V1042= on NM_015172.4) | Silent (SNP) | VAF 146/338 reads (43%) | catalogued as COSV100144492; called by muse, mutect2, varscan2
- PSME4 | c.2853G>A p.R951= | Silent (SNP) | VAF 14/404 reads (3%) | catalogued as COSV66363670; called by muse, mutect2
- PTPN21 | c.85C>T p.L29= | Silent (SNP) | VAF 92/437 reads (21%) | catalogued as COSV100161345, COSV60850122; called by muse, mutect2, varscan2
- SLC6A1 | c.888C>T p.Y296= | Silent (SNP) | VAF 73/500 reads (15%) | catalogued as rs144034291; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZSCAN10 | c.885G>A p.A295= (on ENST00000252463; = p.A350= on NM_032805.3) | Silent (SNP) | VAF 93/427 reads (22%) | catalogued as rs773862495, COSV99373749; called by muse, mutect2, varscan2
- CPLANE1 | c.*2930G>T | 3'UTR (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99949284; called by muse, mutect2
- KIR3DX1 | n.864C>T | RNA (SNP) | VAF 178/732 reads (24%) | catalogued as rs760842823, COSV55597926; called by muse, mutect2
- OSGIN1 | n.1109G>A | RNA (SNP) | VAF 64/330 reads (19%) | catalogued as rs376376327; called by muse, mutect2, varscan2
